Somatic mutation profile of tumor specimen C3N-00496-01 (aliquot CPT0379630015) from CPTAC case C3N-00496, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 54.7 years (19,971 days).
Specimen C3N-00496-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea8277bb-6554-4e74-8ac5-7f996273ff87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00496-31 (Blood Derived Normal), aliquot CPT0379730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4ef4a58-1452-4f17-af1a-e17236353137

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, 5'Flank 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 75/429 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852629, CM941018, COSV59012143; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.7255G>A p.E2419K | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777900, COSV63869451; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACOX1 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs879146160; called by muse, mutect2
- ADGRL4 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs541091913; called by muse, varscan2
- DDAH2 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV65383614; called by muse, mutect2, varscan2
- KRT6B | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 85/699 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV52885708, COSV99360395; called by muse, mutect2, varscan2
- ATP12A | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCAS3 | c.446T>A p.L149H | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCHCR1 | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CNTNAP1 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 9/289 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2
- DDA1 | c.31T>C p.Y11H | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- HRH2 | c.162T>A p.N54K | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRTAP10-3 | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, varscan2
- MYO15A | c.6927del p.P2310Lfs*107 | Frame Shift Del (DEL) | VAF 26/243 reads (11%) | called by pindel, varscan2
- OXCT2 | c.983A>C p.N328T | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PDE7A | c.1341T>A p.N447K (on ENST00000401827 / NM_001242318.3; = p.N421K on NM_002603.4) | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIDD1 | c.1309T>A p.W437R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- STS | c.1039T>G p.S347A | Missense Mutation (SNP) | VAF 72/378 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNMD | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); called by muse, mutect2
- UTP14C | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.124); called by muse, mutect2
- ZBTB18 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC191 | c.969A>G p.Q323= | Silent (SNP) | VAF 41/208 reads (20%) | catalogued as rs1198377286; called by muse, mutect2, varscan2
- MBOAT7 | c.21G>A p.T7= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as rs1280933603; called by muse, mutect2
- MTOR | c.6138C>T p.G2046= | Silent (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- MYH13 | c.1950C>T p.T650= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs769463392, COSV52819824; called by muse, mutect2, varscan2
- NUP160 | c.1398A>G p.Q466= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs757303001; called by muse, mutect2, varscan2
- SLC6A3 | c.180G>A p.R60= | Silent (SNP) | VAF 93/412 reads (23%) | catalogued as COSV54364329; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22613190 C>T | 5'Flank (SNP) | VAF 45/509 reads (9%) | called by muse, mutect2, varscan2
- SCN4B | c.*2488C>T | 3'UTR (SNP) | VAF 79/350 reads (23%) | catalogued as rs1334848711; called by muse, mutect2, varscan2
- TRIM74 | chr7:72969771 G>A | 5'Flank (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
